Somatic mutation profile of tumor specimen 0DVZ18 from CCDI case PBCNMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.4 years (1,607 days).
Specimen 0DVZ18: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d1360fa-1384-4865-98a3-f2483aee244d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aff58142-b536-42e5-9784-379bd60eb7df

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 242/559 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2, varscan2
- NNT | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 34/1146 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM125558, COSV99239216; called by muse, mutect2
- ABCA5 | c.3677A>G p.Q1226R | Missense Mutation (SNP) | VAF 146/1004 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENPP3 | c.1378C>A p.H460N | Missense Mutation (SNP) | VAF 158/1110 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HCFC1 | c.1304C>A p.P435H | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF727 | c.1384A>T p.T462S | Missense Mutation (SNP) | VAF 241/518 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC85A | c.222C>T p.I74= | Silent (SNP) | VAF 94/279 reads (34%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4353G>A p.G1451= | Silent (SNP) | VAF 31/830 reads (4%) | catalogued as COSV62813999; called by muse, mutect2
- PAK3 | c.513+50T>G | Intron (SNP) | VAF 60/820 reads (7%) | called by muse, mutect2
- PM20D2 | c.*8A>T | 3'UTR (SNP) | VAF 15/492 reads (3%) | called by muse, mutect2
